Somatic mutation profile of tumor specimen TCGA-14-1455-01A (aliquot TCGA-14-1455-01A-01W-0643-08) from TCGA case TCGA-14-1455, project TCGA-GBM (Glioblastoma Multiforme). Sex at birth: male; Vital status: Dead; Primary diagnosis: Glioblastoma; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 61.8 years (22,562 days).
Specimen TCGA-14-1455-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) a6611936-3cc8-48f4-a4ef-b2445c5363f0.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-14-1455-10A (Blood Derived Normal), aliquot TCGA-14-1455-10A-01W-0643-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/26f70d72-362e-451f-a363-20aa0180af66

The open-access MAF lists 67 somatic variants for this specimen: 51 protein-altering or splice-affecting, 15 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 42, Silent 15, Nonsense Mutation 3, Frame Shift Del 2, Splice Region 2, Splice Site 1, In Frame Del 1, Intron 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- EGFR | c.1088C>T p.T363I | Missense Mutation (SNP) | VAF 78/341 reads (23%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as rs1164954595, COSV51779091, COSV51843270; called by muse, mutect2, varscan2
- PDGFRA | c.703T>C p.C235R | Missense Mutation (SNP) | VAF 1964/3625 reads (54%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1452760876, COSV57275429; called by muse, mutect2, varscan2
- AGPS | c.521C>G p.S174* | Nonsense Mutation (SNP) | VAF 38/94 reads (40%) | catalogued as COSV51567526, COSV51569866; called by muse, mutect2, varscan2
- ALDH1L1 | c.709G>A p.A237T | Missense Mutation (SNP) | VAF 23/41 reads (56%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.309); catalogued as COSV56420113; called by muse, mutect2, varscan2
- APOB | c.7438T>A p.Y2480N | Missense Mutation (SNP) | VAF 30/451 reads (7%) | SIFT deleterious (0.01); PolyPhen benign (0.312); catalogued as COSV99264508; called by muse, mutect2
- B3GNT2 | c.26A>T p.K9M | Missense Mutation (SNP) | VAF 22/187 reads (12%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.858); catalogued as COSV100114087; called by muse, mutect2, varscan2
- B3GNT4 | c.170G>C p.G57A | Missense Mutation (SNP) | VAF 20/49 reads (41%) | SIFT tolerated (0.29); PolyPhen benign (0.005); catalogued as COSV57337735; called by muse, mutect2, varscan2
- CASQ2 | c.896C>T p.P299L | Missense Mutation (SNP) | VAF 6/48 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as COSV99797222; called by muse, mutect2, varscan2
- CBY2 | c.245G>A p.R82H | Missense Mutation (SNP) | VAF 8/34 reads (24%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.966); catalogued as rs1248037417, COSV60120122; called by muse, mutect2, varscan2
- CCDC125 | c.1451T>C p.I484T | Missense Mutation (SNP) | VAF 106/200 reads (53%) | SIFT tolerated (0.14); PolyPhen benign (0.003); catalogued as COSV67289044; called by muse, mutect2, varscan2
- COL7A1 | c.4553A>G p.K1518R | Missense Mutation (SNP) | VAF 7/11 reads (64%) | SIFT tolerated (0.35); PolyPhen benign (0.127); catalogued as COSV100095459; called by muse, mutect2, varscan2
- CRIM1 | c.2900T>G p.I967R | Missense Mutation (SNP) | VAF 55/138 reads (40%) | SIFT deleterious (0); PolyPhen benign (0.424); catalogued as COSV54874083; called by muse, mutect2, varscan2
- DNAH9 | c.9940A>G p.N3314D | Missense Mutation (SNP) | VAF 8/90 reads (9%) | SIFT tolerated (0.99); PolyPhen benign (0.013); catalogued as COSV99304896; called by muse, mutect2, varscan2
- DNAJC13 | c.3982G>A p.A1328T | Missense Mutation (SNP) | VAF 7/73 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV99606917; called by muse, mutect2, varscan2
- DRC7 | c.934C>T p.R312C | Missense Mutation (SNP) | VAF 6/14 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs772920234, COSV100395454; called by muse, varscan2
- ENAM | c.767C>T p.P256L | Missense Mutation (SNP) | VAF 33/91 reads (36%) | SIFT deleterious (0); PolyPhen possibly damaging (0.543); catalogued as COSV68537265; called by muse, mutect2, varscan2
- EPG5 | c.3238C>G p.Q1080E | Missense Mutation (SNP) | VAF 63/170 reads (37%) | SIFT deleterious (0.04); PolyPhen benign (0.02); catalogued as COSV56357076; called by muse, mutect2, varscan2
- FCGR3B | c.380G>A p.R127K | Missense Mutation (SNP) | VAF 35/78 reads (45%) | SIFT tolerated (0.12); PolyPhen benign (0.044); catalogued as COSV54212544, COSV99670540; called by muse, mutect2, varscan2
- FCRL6 | c.973G>A p.A325T | Missense Mutation (SNP) | VAF 73/523 reads (14%) | SIFT deleterious (0.03); PolyPhen benign (0.312); catalogued as COSV100220099; called by muse, mutect2, varscan2
- FKBP5 | c.1217G>A p.R406H | Missense Mutation (SNP) | VAF 100/181 reads (55%) | SIFT deleterious (0); PolyPhen benign (0.003); catalogued as rs148272640; called by muse, mutect2, varscan2
- FLG | c.8200C>T p.H2734Y | Missense Mutation (SNP) | VAF 44/320 reads (14%) | SIFT deleterious (0.03); PolyPhen benign (0.202); catalogued as rs769096798, COSV100911229; called by muse, mutect2, varscan2
- G6PC | c.970G>A p.V324I | Missense Mutation (SNP) | VAF 286/674 reads (42%) | SIFT tolerated (0.83); PolyPhen benign (0); catalogued as rs376389208; called by muse, mutect2, varscan2
- GRM6 | c.2305G>T p.A769S | Missense Mutation (SNP) | VAF 7/64 reads (11%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.993); catalogued as COSV104370830, COSV99179507; called by muse, mutect2, varscan2
- IGSF10 | c.2147G>C p.S716T | Missense Mutation (SNP) | VAF 95/225 reads (42%) | SIFT tolerated (0.48); PolyPhen benign (0.115); catalogued as COSV56793004; called by muse, mutect2, varscan2
- KMT2C | c.14543A>G p.N4848S | Missense Mutation (SNP) | VAF 77/366 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV51507607; called by muse, mutect2, varscan2
- KRT71 | c.978G>A p.K326= | Splice Region (SNP) | VAF 65/161 reads (40%) | catalogued as COSV57293472; called by muse, mutect2, varscan2
- LYST | c.7832_7833del p.R2611Lfs*5 | Frame Shift Del (DEL) | VAF 43/110 reads (39%) | catalogued as COSV67715336; called by mutect2, pindel, varscan2
- MED13 | c.4211A>G p.H1404R | Missense Mutation (SNP) | VAF 42/87 reads (48%) | SIFT deleterious (0); PolyPhen possibly damaging (0.838); catalogued as COSV67267673; called by muse, mutect2, varscan2
- MYO3B | c.3731C>G p.P1244R | Missense Mutation (SNP) | VAF 43/94 reads (46%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.014); catalogued as COSV58720448; called by muse, mutect2, varscan2
- NAALAD2 | c.889C>A p.R297S | Missense Mutation (SNP) | VAF 32/91 reads (35%) | SIFT tolerated (0.35); PolyPhen benign (0.152); catalogued as COSV58967049; called by muse, mutect2, varscan2
- NAB1 | c.457C>T p.Q153* | Nonsense Mutation (SNP) | VAF 17/127 reads (13%) | catalogued as COSV100492916; called by muse, mutect2, varscan2
- NPAS3 | c.1527del p.N509Kfs*3 (on ENST00000356141 / NM_001164749.2; = p.N477Kfs*3 on NM_022123.3) | Frame Shift Del (DEL) | VAF 8/15 reads (53%) | catalogued as COSV60867189; called by mutect2, pindel
- NR0B2 | c.370G>A p.E124K | Missense Mutation (SNP) | VAF 21/50 reads (42%) | SIFT tolerated (0.47); PolyPhen benign (0.339); catalogued as COSV54260333; called by muse, mutect2, varscan2
- OR4C12 | c.841A>T p.N281Y | Missense Mutation (SNP) | VAF 90/191 reads (47%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.948); catalogued as COSV58861316; called by muse, mutect2
- OR8B2 | c.488T>A p.M163K | Missense Mutation (SNP) | VAF 21/98 reads (21%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.979); catalogued as COSV66665624; called by muse, mutect2
- PAN3 | c.1561C>T p.R521W | Missense Mutation (SNP) | VAF 47/119 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs763986840, COSV56704360; called by muse, mutect2, varscan2
- PDGFRA | c.1027C>T p.P343S | Missense Mutation (SNP) | VAF 104/2584 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV57272357; called by muse, mutect2
- PDZRN3 | c.2929G>A p.E977K | Missense Mutation (SNP) | VAF 43/114 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV55217746; called by muse, mutect2, varscan2
- PPFIA3 | c.731G>A p.R244Q | Missense Mutation (SNP) | VAF 12/25 reads (48%) | SIFT tolerated (0.06); PolyPhen benign (0.019); catalogued as rs1435446625, COSV100494737; called by muse, mutect2, varscan2
- RAB3C | c.182G>A p.S61N | Missense Mutation (SNP) | VAF 27/79 reads (34%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.981); catalogued as COSV51443289; called by muse, mutect2, varscan2
- RIMS2 | c.1783C>T p.R595* (on ENST00000666250 / NM_001348490.2; = p.R403* on NM_014677.5 and 7 other RefSeq transcripts) | Nonsense Mutation (SNP) | VAF 38/101 reads (38%) | catalogued as COSV51730614; called by muse, mutect2, varscan2
- SLC38A4 | c.587T>A p.L196H | Missense Mutation (SNP) | VAF 36/91 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as COSV56972025; called by muse, mutect2, varscan2
- SYCP1 | c.610C>T p.R204W | Missense Mutation (SNP) | VAF 60/148 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1447626669, COSV65698038; called by muse, mutect2, varscan2
- TUBB | c.409C>T p.H137Y | Missense Mutation (SNP) | VAF 8/200 reads (4%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.984); catalogued as COSV100013298; called by muse, mutect2
- UBTF | c.475-3dup | Splice Region (INS) | VAF 4/40 reads (10%) | catalogued as rs753096746; called by pindel, varscan2
- USP34 | c.2834+2T>G p.X945_splice | Splice Site (SNP) | VAF 16/32 reads (50%) | catalogued as COSV101276825; called by muse, mutect2, varscan2
- WDR49 | c.883C>G p.Q295E (on ENST00000308378 / NM_001366158.1; = p.Q636E on NM_001348951.2 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 67/152 reads (44%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.76); catalogued as COSV57719252; called by muse, mutect2, varscan2
- WNT2 | c.958C>T p.R320W | Missense Mutation (SNP) | VAF 38/127 reads (30%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.969); catalogued as rs771192645, COSV55414288; called by muse, mutect2, varscan2
- ZHX1 | c.1741C>T p.R581C | Missense Mutation (SNP) | VAF 75/150 reads (50%) | SIFT deleterious (0.02); PolyPhen benign (0.417); catalogued as rs138343253; called by muse, mutect2, varscan2
- KIF6 | c.781_810del p.G261_A270del | In Frame Del (DEL) | VAF 45/194 reads (23%) | called by mutect2, pindel*
- TPP2 | c.943A>C p.I315L | Missense Mutation (SNP) | VAF 14/124 reads (11%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.754); called by mutect2, varscan2
- ANKRD34B | c.231C>T p.P77= | Silent (SNP) | VAF 42/326 reads (13%) | catalogued as COSV100103421; called by muse, varscan2
- ANKRD34B | c.159C>T p.T53= | Silent (SNP) | VAF 34/310 reads (11%) | catalogued as COSV100103422; called by muse, varscan2
- ARID1B | c.1842G>A p.A614= | Silent (SNP) | VAF 14/35 reads (40%) | catalogued as rs146312104, COSV51683891; called by muse, mutect2, varscan2
- ATP6V0A4 | c.2238C>T p.A746= | Silent (SNP) | VAF 17/42 reads (40%) | catalogued as rs1245982313, COSV59481364; called by muse, mutect2, varscan2
- CLDN11 | c.267G>A p.S89= | Silent (SNP) | VAF 102/208 reads (49%) | catalogued as COSV50356329; called by muse, mutect2, varscan2
- FGF5 | c.552A>C p.T184= | Silent (SNP) | VAF 64/175 reads (37%) | catalogued as COSV56892285; called by muse, mutect2, varscan2
- HECW1 | c.2163C>T p.S721= | Silent (SNP) | VAF 49/173 reads (28%) | catalogued as rs201225073; called by muse, mutect2, varscan2
- KRT33B | c.960C>T p.N320= | Silent (SNP) | VAF 80/210 reads (38%) | catalogued as rs957298824, COSV52442803; called by muse, mutect2, varscan2
- LLCFC1 | c.324G>A p.S108= (on ENST00000458732; = p.S77= on NM_178829.5 and 1 other RefSeq transcript) | Silent (SNP) | VAF 55/258 reads (21%) | catalogued as rs767114431, COSV62338099; called by muse, mutect2, varscan2
- OR5T3 | c.150C>T p.T50= | Silent (SNP) | VAF 22/193 reads (11%) | catalogued as rs940441878, COSV100282733, COSV57381062; called by muse, mutect2, varscan2
- PIGR | c.1608G>A p.R536= | Silent (SNP) | VAF 12/163 reads (7%) | called by muse, mutect2
- SLIT2 | c.3147C>T p.H1049= | Silent (SNP) | VAF 20/75 reads (27%) | catalogued as rs756872945, COSV56582524, COSV56598699; called by muse, mutect2, varscan2
- ST6GAL2 | c.69T>C p.F23= | Silent (SNP) | VAF 27/59 reads (46%) | catalogued as rs1243788826, COSV64532499; called by muse, mutect2, varscan2
- TBX4 | c.939C>A p.L313= | Silent (SNP) | VAF 17/51 reads (33%) | catalogued as COSV53606573, COSV53610218; called by muse, mutect2, varscan2
- ZNF473 | c.105G>A p.A35= | Silent (SNP) | VAF 41/124 reads (33%) | catalogued as rs374998578; called by muse, mutect2, varscan2
- KLK8 | c.71-100G>A | Intron (SNP) | VAF 5/21 reads (24%) | catalogued as COSV51592190; called by muse, mutect2
